Somatic mutation profile of tumor specimen TCGA-73-4666-01A (aliquot TCGA-73-4666-01A-01D-1265-08) from TCGA case TCGA-73-4666, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 52.2 years (19,074 days).
Specimen TCGA-73-4666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91bc73cd-f60f-4723-9aed-c7043e2ba529.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-4666-11A (Solid Tissue Normal), aliquot TCGA-73-4666-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b83cff33-e595-4835-8e5f-f03cc0713016

The open-access MAF lists 406 somatic variants for this specimen: 302 protein-altering or splice-affecting, 98 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 268, Silent 98, Nonsense Mutation 15, Frame Shift Del 9, Splice Site 7, Intron 2, RNA 2, Frame Shift Ins 2, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIT1 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 59/123 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs869025191, CM149836, CM161971, CM161972, COSV64170884, COSV64171290, COSV64171744; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 53/103 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABCA12 | c.5770C>A p.L1924I (on ENST00000272895 / NM_173076.3; = p.L1606I on NM_015657.3) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.465); catalogued as COSV55962334, COSV99787971; called by muse, mutect2, varscan2
- ABCA13 | c.2348G>C p.R783T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs376264174; called by muse, mutect2, varscan2
- ABCC11 | c.2227C>A p.Q743K | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV62323724; called by muse, mutect2, varscan2
- ABCG2 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV52946682; called by muse, mutect2
- ABRA | c.797G>C p.S266T | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61732628; called by muse, mutect2, varscan2
- AC005324.2 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100371849; called by muse, mutect2
- ACKR1 | c.88T>A p.Y30N | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.903); catalogued as COSV63673160, COSV63673176; called by muse, mutect2, varscan2
- ACOXL | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV61323510; called by muse, mutect2, varscan2
- ACSM2B | c.1622C>G p.P541R | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61658198; called by muse, mutect2, varscan2
- ADAMTS14 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64602859; called by muse, mutect2, varscan2
- ADAMTS19 | c.2745C>A p.S915R | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV50754696, COSV50794026; called by muse, mutect2, varscan2
- ADAMTS19 | c.3245C>T p.P1082L | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50754762; called by muse, mutect2, varscan2
- ADAMTS5 | c.1444G>T p.G482C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV53179986; called by muse, mutect2, varscan2
- ADH1B | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59296617; called by muse, mutect2, varscan2
- AGO2 | c.542T>C p.F181S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55048360; called by muse, mutect2, varscan2
- AHNAK2 | c.1315A>T p.R439W | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV60917910; called by muse, mutect2, varscan2
- AKAP6 | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 22/174 reads (13%) | catalogued as COSV55216763, COSV55234202; called by muse, mutect2, varscan2
- AKAP6 | c.6077G>T p.G2026V | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55205381, COSV55216773; called by muse, mutect2, varscan2
- ANK2 | c.9370T>A p.Y3124N | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52166149; called by muse, mutect2, varscan2
- ANK2 | c.11605G>A p.E3869K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.157); catalogued as COSV52166160, COSV52170232; called by muse, mutect2, varscan2
- ANO3 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 108/228 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as rs150999282; called by muse, mutect2, varscan2
- ANO4 | c.1464G>T p.K488N (on ENST00000392977 / NM_001286615.2; = p.K453N on NM_178826.4) | Missense Mutation (SNP) | VAF 91/145 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV54598727; called by muse, mutect2, varscan2
- AP002512.3 | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99687905; called by muse, mutect2, varscan2
- AP2M1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53048513; called by muse, mutect2, varscan2
- AP3S1 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.265); catalogued as rs554915045, COSV57475178; called by muse, mutect2
- AQR | c.2878G>T p.D960Y | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV50036652; called by muse, mutect2, varscan2
- ARAP2 | c.2950G>A p.G984R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58287851; called by muse, mutect2, varscan2
- ARHGEF12 | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.205); catalogued as COSV63105333; called by muse, mutect2
- ASB15 | c.1127C>A p.P376Q | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51926671; called by muse, mutect2, varscan2
- ASTN1 | c.3000G>T p.E1000D | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0.009); catalogued as COSV62498354; called by muse, mutect2, varscan2
- ATRX | c.3899A>G p.K1300R | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV64877963; called by muse, mutect2, varscan2
- BACH1 | c.2048G>T p.C683F | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99728164; called by muse, mutect2, varscan2
- BDP1 | c.4247+1G>T p.X1416_splice | Splice Site (SNP) | VAF 18/72 reads (25%) | catalogued as COSV62431959; called by muse, mutect2, varscan2
- BOD1L1 | c.3325G>C p.G1109R | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV50017541; called by muse, mutect2, varscan2
- BRINP3 | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 82/492 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.102); catalogued as COSV66527267; called by muse, mutect2, varscan2
- BRWD3 | c.3603-1G>T p.X1201_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | catalogued as COSV64749172; called by muse, mutect2
- C1QTNF2 | c.343G>C p.G115R (on ENST00000393975; = p.G70R on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67432822; called by muse, mutect2, varscan2
- C1orf141 | c.1070C>G p.T357R | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV63992794; called by muse, mutect2, varscan2
- C1orf94 | c.1792T>G p.F598V (on ENST00000488417 / NM_001134734.2; = p.F408V on NM_032884.5) | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64914296, COSV64914459; called by muse, mutect2, varscan2
- C4orf17 | c.223A>T p.R75W | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV58512721; called by muse, mutect2
- CACNA1E | c.3529C>A p.L1177M | Missense Mutation (SNP) | VAF 91/223 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV100702265; called by muse, mutect2, varscan2
- CACNA1E | c.3530T>A p.L1177Q | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100702268; called by muse, mutect2, varscan2
- CACNA1E | c.6266G>A p.R2089Q (on ENST00000367573 / NM_001205293.3; = p.R2046Q on NM_000721.4) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs779786799, COSV62385435; called by muse, mutect2, varscan2
- CACNA1F | c.3053G>T p.G1018V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59904408; called by muse, mutect2
- CACNG3 | c.199T>A p.C67S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV50070283; called by muse, mutect2, varscan2
- CALML3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.093); catalogued as rs755749919, COSV59449468; called by mutect2, varscan2
- CAMTA1 | c.2915-2A>G p.X972_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV57905621; called by muse, mutect2, varscan2
- CAPN7 | c.1454G>T p.W485L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53778806; called by muse, mutect2, varscan2
- CASP2 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as COSV60082502; called by muse, mutect2, varscan2
- CASR | c.2429C>G p.A810G (on ENST00000490131; = p.A887G on NM_000388.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56138092, COSV56138348; called by muse, mutect2, varscan2
- CCDC178 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs1318278388, COSV55777405; called by muse, mutect2, varscan2
- CCKAR | c.229A>C p.N77H | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55161986; called by muse, mutect2, varscan2
- CCL28 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV63149483; called by muse, mutect2, varscan2
- CD226 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.38); catalogued as rs1449941436, COSV54612848; called by muse, mutect2, varscan2
- CDK6 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56008978; called by muse, mutect2, varscan2
- CFAP70 | c.1210A>T p.K404* | Nonsense Mutation (SNP) | VAF 59/236 reads (25%) | catalogued as COSV60283910; called by muse, mutect2, varscan2
- CGNL1 | c.2470G>A p.V824M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs574028211, COSV99848127; called by muse, mutect2, varscan2
- CHM | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.291); catalogued as COSV63302373; called by muse, mutect2, varscan2
- CIITA | c.1522G>C p.D508H | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60858333; called by muse, mutect2, varscan2
- CNGA4 | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV66006181, COSV66006944; called by muse, mutect2, varscan2
- COL11A1 | c.426C>A p.H142Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV62185792; called by muse, mutect2, varscan2
- COL5A2 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776302656, COSV66410354, COSV66410598; called by muse, mutect2, varscan2
- COP1 | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV58168958; called by muse, mutect2, varscan2
- CPS1 | c.3917T>C p.V1306A | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV51812801; called by muse, mutect2, varscan2
- CSNK1A1L | c.223del p.H75Tfs*14 | Frame Shift Del (DEL) | VAF 30/217 reads (14%) | catalogued as COSV101131125; called by mutect2, pindel, varscan2
- CSNK1G3 | c.1308A>C p.K436N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.91); catalogued as rs778817415, COSV62055058; called by muse, mutect2, varscan2
- CTAGE1 | c.850A>T p.K284* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV66943722; called by muse, mutect2, varscan2
- CYFIP2 | c.1594T>G p.L532V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); catalogued as COSV59041025; called by muse, varscan2
- CYLC2 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV66336461, COSV66339631; called by muse, mutect2, varscan2
- CYP4F8 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as COSV57854296; called by muse, mutect2, varscan2
- DCAF4 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62319788; called by muse, mutect2, varscan2
- DDHD2 | c.770A>G p.Q257R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV68158050; called by muse, mutect2, varscan2
- DGAT1 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60048358; called by muse, mutect2, varscan2
- DOCK2 | c.3856G>A p.G1286S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV56963274; called by muse, mutect2
- DOCK3 | c.1516C>A p.R506S | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56527194; called by muse, mutect2, varscan2
- DOCK9 | c.4810A>T p.K1604* (on ENST00000376460 / NM_001366676.2; = p.K1605* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV59632422; called by muse, mutect2, varscan2
- DOLK | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 110/182 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV58280356; called by muse, mutect2, varscan2
- EDEM3 | c.2791G>T p.E931* | Nonsense Mutation (SNP) | VAF 8/83 reads (10%) | catalogued as COSV58925085; called by muse, mutect2, varscan2
- ELL3 | c.715A>G p.S239G | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV55856693; called by muse, mutect2, varscan2
- EPSTI1 | c.829C>A p.H277N (on ENST00000398762 / NM_001330543.2; = p.H266N on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as COSV58045978; called by muse, mutect2, varscan2
- ERC2 | c.2502A>C p.E834D | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV55603056, COSV55629105; called by muse, mutect2, varscan2
- ETFBKMT | c.102T>G p.C34W | Missense Mutation (SNP) | VAF 122/206 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.122); catalogued as COSV100740367; called by muse, varscan2
- EXOSC7 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55556887; called by muse, varscan2
- FAM172A | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV67938515; called by muse, mutect2, varscan2
- FAM83C | c.1003G>T p.V335F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV65581887, COSV65583361; called by muse, mutect2, varscan2
- FANCG | c.1510A>T p.K504* | Nonsense Mutation (SNP) | VAF 32/106 reads (30%) | catalogued as COSV62720880; called by muse, mutect2, varscan2
- FAT3 | c.4252G>T p.A1418S | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53122447, COSV53175695, COSV99969666; called by muse, mutect2, varscan2
- FBXO33 | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99980858; called by muse, mutect2, varscan2
- FGF12 | c.341G>T p.R114L (on ENST00000454309 / NM_021032.5; = p.R52L on NM_004113.6) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as CM166790, COSV53173851; called by muse, varscan2
- FGF12 | c.340C>G p.R114G (on ENST00000454309 / NM_021032.5; = p.R52G on NM_004113.6) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.936); catalogued as COSV53157372, COSV53160867, COSV53190624; called by muse, varscan2
- FOLH1 | c.883C>A p.H295N | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV57050435; called by muse, varscan2
- FRMPD1 | c.4535G>T p.R1512L | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs377415527, COSV66700691; called by muse, mutect2, varscan2
- FRMPD2 | c.3613C>A p.Q1205K | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV59718917; called by mutect2, varscan2
- FSTL5 | c.569A>T p.D190V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100054781; called by muse, mutect2
- GABRA1 | c.545T>A p.L182Q | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50107050; called by muse, mutect2, varscan2
- GABRB3 | c.971A>C p.Y324S | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54668303; called by muse, mutect2, varscan2
- GABRG2 | c.1139C>A p.S380Y (on ENST00000361925 / NM_001375343.1; = p.S340Y on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100729386, COSV62718810; called by muse, mutect2, varscan2
- GCLC | c.1057_1060del p.D353Kfs*29 (on ENST00000643939; = p.D351Kfs*29 on NM_001498.4) | Frame Shift Del (DEL) | VAF 58/172 reads (34%) | catalogued as rs746901555; called by pindel, varscan2
- GDF6 | c.1174C>G p.R392G | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54622869, COSV54625601; called by muse, mutect2, varscan2
- GFI1B | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1462798363, COSV100253925; called by muse, mutect2, varscan2
- GFI1B | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs367947845, COSV100254119; called by muse, mutect2, varscan2
- GOT2 | c.445T>G p.F149V | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV55331945; called by muse, mutect2, varscan2
- GPRIN1 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV56140158, COSV56143071; called by muse, mutect2, varscan2
- GRIN3A | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV62454755; called by muse, mutect2, varscan2
- GRM5 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100554260, COSV59609032; called by muse, mutect2, varscan2
- GRM7 | c.2555C>A p.P852H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63147175; called by muse, mutect2, varscan2
- GRM8 | c.1917G>T p.M639I | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as rs1390888073, COSV58805588, COSV58869408; called by muse, varscan2
- GTF2E1 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV52204663; called by muse, mutect2, varscan2
- H2AC20 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.073); catalogued as COSV58612228; called by muse, mutect2, varscan2
- HDAC1 | c.895G>T p.G299* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV61482104; called by muse, mutect2, varscan2
- HDAC9 | c.2392G>T p.V798F | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV67775181; called by muse, mutect2, varscan2
- HERC2 | c.6788T>C p.L2263P | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV55327951; called by muse, mutect2
- HOXB1 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV53316586, COSV99495463; called by muse, mutect2, varscan2
- HSPA8 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as COSV57082400; called by muse, mutect2
- HUNK | c.1672A>G p.M558V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs751030404, COSV54229462; called by muse, mutect2, varscan2
- HUWE1 | c.266T>A p.L89Q | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.651); catalogued as COSV53348696; called by muse, mutect2, varscan2
- IDUA | c.386-2A>C p.X129_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | catalogued as CS941502, COSV99925867; called by muse, varscan2
- IGSF9B | c.3820G>T p.G1274C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.423); catalogued as rs1346837415, COSV58068808; called by muse, mutect2, varscan2
- IKBKE | c.2012A>C p.Y671S | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65623351; called by muse, mutect2, varscan2
- IL2RG | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV52148748; called by muse, mutect2, varscan2
- IQGAP2 | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV57175134, COSV99169268; called by muse, mutect2
- KBTBD2 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV58363604; called by muse, mutect2, varscan2
- KCNA10 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63904764; called by mutect2, varscan2
- KCNB1 | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV65566922, COSV65568775; called by muse, mutect2, varscan2
- KDM6B | c.304del p.R102Gfs*96 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | catalogued as COSV99641665; called by mutect2, pindel, varscan2
- KDR | c.1490T>C p.I497T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs765732771, COSV55767201; called by muse, mutect2, varscan2
- KDR | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99817490; called by muse, mutect2, varscan2
- KDR | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV99817493; called by muse, mutect2, varscan2
- KEAP1 | c.1807G>T p.G603W | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50294325; called by muse, mutect2, varscan2
- KHDRBS3 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV104419625, COSV63419725; called by muse, mutect2, varscan2
- KLHL31 | c.1367G>T p.R456L | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs751426893, COSV100911812, COSV63881933; called by muse, mutect2, varscan2
- KLK2 | c.330C>A p.S110R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.222); catalogued as COSV57569870; called by muse, mutect2, varscan2
- KMT2B | c.4312G>A p.D1438N | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV55862763; called by muse, mutect2, varscan2
- KMT5B | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58566803; called by muse, mutect2
- KRT1 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV52867300; called by muse, mutect2, varscan2
- KRT85 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57737177; called by muse, mutect2, varscan2
- KRTAP23-1 | c.73T>A p.S25T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV61935694; called by muse, mutect2, varscan2
- LAT2 | c.372C>G p.F124L | Missense Mutation (SNP) | VAF 65/504 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV51921188, COSV51921294, COSV51921543; called by muse, varscan2
- LATS2 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66874049, COSV66876520; called by muse, mutect2, varscan2
- LDHD | c.1112A>G p.H371R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55581115; called by muse, mutect2, varscan2
- LILRB1 | c.308C>A p.A103E (on ENST00000427581; = p.A67E on NM_006669.6) | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.127); catalogued as COSV61118912; called by muse, mutect2, varscan2
- LMOD1 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1011855307, COSV66172934; called by muse, mutect2, varscan2
- LPA | c.3369G>T p.W1123C | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV60303354; called by muse, mutect2, varscan2
- LRIT2 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.739); catalogued as COSV60563169; called by muse, mutect2, varscan2
- LRP1B | c.10033G>C p.G3345R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.19); catalogued as COSV101257783, COSV67189219, COSV67231331; called by muse, mutect2, varscan2
- LRRC4C | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV53428001; called by muse, mutect2, varscan2
- MALT1 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61935142; called by muse, mutect2, varscan2
- MAN2C1 | c.3073C>T p.P1025S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51230317; called by muse, mutect2, varscan2
- MAOA | c.1435A>T p.K479* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as COSV58643328; called by muse, mutect2, varscan2
- MAPK10 | c.73C>T p.R25C (on ENST00000359221 / NM_001351625.2; = p.R63C on NM_002753.5) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773390425, COSV60384294; called by muse, mutect2, varscan2
- MCU | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 74/342 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as COSV64066548; called by muse, mutect2, varscan2
- MECP2 | c.909C>G p.I303M | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs61751439, CM041388, COSV57654475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MGAM | c.4223C>A p.P1408Q | Missense Mutation (SNP) | VAF 65/104 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV72074840; called by muse, mutect2, varscan2
- MMP2 | c.1133C>A p.T378K | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs1173162126, COSV54602127; called by muse, mutect2, varscan2
- MOGAT1 | c.869C>G p.P290R | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV71479924; called by muse, varscan2
- MRTFB | c.2521G>T p.A841S (on ENST00000571589 / NM_001365412.2; = p.A791S on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as COSV57958733; called by muse, mutect2, varscan2
- MS4A12 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs138899173; called by muse, mutect2, varscan2
- MTM1 | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV60335442; called by muse, mutect2, varscan2
- MTUS2 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV70917267, COSV70917359; called by muse, mutect2, varscan2
- MXRA8 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.606); catalogued as rs753146996, COSV58510825; called by muse, mutect2, varscan2
- MYH2 | c.3773T>C p.L1258P | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55440096; called by muse, mutect2, varscan2
- MYLK | c.378T>A p.S126R | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV60612304; called by muse, mutect2, varscan2
- MYO1H | c.1595A>T p.K532M | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as COSV60446522; called by muse, mutect2, varscan2
- NAV3 | c.3653C>A p.P1218H | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57085553; called by muse, varscan2
- NCAM1 | c.1229T>A p.L410H (on ENST00000316851 / NM_181351.5; = p.L400H on NM_000615.7) | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57518081; called by muse, mutect2, varscan2
- NCOA6 | c.5305G>T p.D1769Y | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV62864548; called by muse, mutect2, varscan2
- NEGR1 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60849596; called by muse, mutect2, varscan2
- NLRP2 | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV54756235; called by muse, mutect2, varscan2
- NLRP4 | c.2143T>A p.C715S | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV56715542; called by muse, mutect2, varscan2
- NME5 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99496811; called by muse, mutect2, varscan2
- NMUR2 | c.385G>C p.V129L | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886131591, COSV54920086, COSV54923170; called by muse, mutect2, varscan2
- NOD2 | c.836A>T p.E279V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV56051800; called by muse, mutect2, varscan2
- NOL4L | c.88A>T p.N30Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV100393992; called by muse, mutect2, varscan2
- NOS2 | c.2207G>T p.R736M | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV58223708, COSV58224224, COSV58224482; called by muse, mutect2, varscan2
- NPFFR2 | c.1133T>A p.L378H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58150573; called by muse, mutect2, varscan2
- NPHP4 | c.2104A>G p.I702V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV65395432; called by muse, mutect2, varscan2
- NPTX1 | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV60774232, COSV60775369; called by muse, mutect2, varscan2
- NPY5R | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58452375; called by muse, mutect2, varscan2
- NPY5R | c.492G>T p.W164C | Missense Mutation (SNP) | VAF 63/358 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58451434, COSV58452386; called by muse, mutect2, varscan2
- OLFM3 | c.1297C>A p.P433T (on ENST00000338858 / NM_001288821.1; = p.P413T on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58799558; called by muse, mutect2, varscan2
- OR10J1 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.311); catalogued as COSV71128987; called by muse, mutect2, varscan2
- OR2G2 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 125/302 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60740797; called by muse, mutect2, varscan2
- OR2M4 | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60708476; called by muse, mutect2, varscan2
- OR4K17 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 18/114 reads (16%) | catalogued as COSV100210637; called by muse, mutect2, varscan2
- OR4K17 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100210641; called by muse, mutect2, varscan2
- OR51G2 | c.431C>G p.T144R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV58993356, COSV58995676; called by muse, mutect2, varscan2
- OR51V1 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV58315402; called by muse, mutect2, varscan2
- OR52K1 | c.725C>A p.T242K | Missense Mutation (SNP) | VAF 135/245 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV56903923; called by muse, mutect2, varscan2
- OR5B3 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV58677637; called by muse, mutect2, varscan2
- OR5T2 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57589113; called by muse, mutect2, varscan2
- OSER1 | c.433del p.A145Qfs*6 | Frame Shift Del (DEL) | VAF 45/164 reads (27%) | catalogued as COSV54853301; called by mutect2, varscan2
- OTOGL | c.6206G>T p.C2069F (on ENST00000547103; = p.C2060F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087199; called by muse, mutect2, varscan2
- P2RY10 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as COSV50681983; called by muse, mutect2, varscan2
- PABPC3 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99879443; called by muse, mutect2, varscan2
- PALMD | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54165014; called by muse, mutect2, varscan2
- PAPOLB | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68201522; called by muse, mutect2, varscan2
- PAPPA2 | c.4129G>T p.G1377W | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); catalogued as COSV62791228; called by muse, mutect2
- PARD3B | c.3579G>T p.Q1193H (on ENST00000406610 / NM_001302769.2; = p.Q1124H on NM_057177.7) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100593252; called by muse, mutect2, varscan2
- PARD3B | c.3580G>T p.D1194Y (on ENST00000406610 / NM_001302769.2; = p.D1125Y on NM_057177.7) | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100593254; called by muse, mutect2, varscan2
- PCDH15 | c.5858C>A p.T1953N | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57327167; called by muse, mutect2, varscan2
- PCDH17 | c.3125C>A p.A1042E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV64973464, COSV64975027; called by muse, mutect2, varscan2
- PCDHA4 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.704); catalogued as rs781997820, COSV63542572, COSV63544995; called by muse, varscan2
- PDK1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 22/118 reads (19%) | catalogued as COSV99961273; called by muse, mutect2, varscan2
- PEG10 | c.11G>A p.R4Q (on ENST00000482108 / NM_001040152.2; = p.R38Q on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV71787963; called by muse, mutect2
- PKP1 | c.1873C>G p.H625D | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.428); catalogued as COSV55822048; called by muse, mutect2, varscan2
- PLBD2 | c.1380G>C p.Q460H | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.152); catalogued as rs551944264, COSV55107205; called by muse, mutect2, varscan2
- PLPPR5 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV54174199, COSV99587802; called by muse, mutect2, varscan2
- PLXNA4 | c.1602C>A p.N534K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV58132633; called by muse, mutect2
- POLR3B | c.1883G>A p.S628N | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV57279988; called by muse, mutect2
- POTEF | c.2781G>A p.M927I | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV62541585; called by muse, mutect2, varscan2
- POU5F2 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67938511; called by muse, mutect2, varscan2
- PPP1R3A | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV52884436, COSV99494657; called by muse, mutect2
- PRDM9 | c.434C>A p.S145* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV57007574; called by muse, varscan2
- PRKCE | c.808G>C p.G270R | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60320660; called by muse, varscan2
- PUM1 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs769733496, COSV57086651; called by muse, mutect2, varscan2
- RABGAP1L | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV52300722, COSV99273790; called by muse, mutect2
- RAD51D | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV60005091; called by muse, mutect2, varscan2
- RAD9A | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57237156; called by muse, mutect2, varscan2
- RELN | c.5043T>G p.S1681R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.174); catalogued as COSV59008026; called by muse, mutect2
- RESF1 | c.4061G>C p.G1354A | Missense Mutation (SNP) | VAF 88/134 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1197935443, COSV57022867; called by muse, mutect2, varscan2
- RGL1 | c.1508A>T p.D503V (on ENST00000360851 / NM_001297672.2; = p.D538V on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV100486453, COSV100486601; called by muse, mutect2, varscan2
- RGS12 | c.3293G>T p.R1098L | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58753073; called by muse, mutect2, varscan2
- RGS6 | c.240A>C p.E80D | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as COSV59567462, COSV59569571; called by muse, mutect2, varscan2
- RIMS2 | c.2950G>T p.D984Y (on ENST00000666250 / NM_001348490.2; = p.D792Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51689157; called by muse, mutect2, varscan2
- RIMS4 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65719835; called by muse, varscan2
- ROBO3 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV67300940, COSV67301339; called by muse, mutect2, varscan2
- RYR2 | c.7606G>T p.A2536S | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.524); catalogued as COSV63690172; called by muse, mutect2, varscan2
- RYR3 | c.3165C>A p.D1055E | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as COSV66793827; called by muse, mutect2, varscan2
- SASH3 | c.681C>G p.I227M | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63556054; called by muse, mutect2, varscan2
- SCN2A | c.4630A>T p.N1544Y | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51844340; called by muse, mutect2, varscan2
- SCN8A | c.4900G>A p.A1634T | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs996870199, COSV61978792; called by muse, mutect2, varscan2
- SCNM1 | c.257A>G p.K86R | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV54860994; called by muse, mutect2, varscan2
- SEC14L3 | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs1446936836, COSV53179747; called by muse, mutect2, varscan2
- SERPINA3 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as COSV67586341; called by muse, mutect2, varscan2
- SERPINA5 | c.161G>T p.R54M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV61574934; called by muse, mutect2, varscan2
- SERPINA5 | c.162G>T p.R54S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100291590; called by muse, mutect2, varscan2
- SETD2 | c.4550G>T p.G1517V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57439982; called by muse, mutect2, varscan2
- SETDB1 | c.3175C>G p.R1059G | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.095); catalogued as COSV54984717; called by muse, varscan2
- SLC12A1 | c.979C>A p.Q327K | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57710053; called by muse, mutect2, varscan2
- SLC12A5 | c.2756G>A p.S919N (on ENST00000454036 / NM_001134771.2; = p.S896N on NM_020708.5) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV54794884; called by muse, mutect2, varscan2
- SLC15A3 | c.977A>G p.Y326C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57172053; called by muse, mutect2, varscan2
- SLC39A11 | c.560G>T p.G187V (on ENST00000542342 / NM_001159770.2; = p.G180V on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV55290849; called by muse, mutect2, varscan2
- SLC8A1 | c.1629G>T p.E543D | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV60483387; called by muse, mutect2, varscan2
- SLC9A2 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.52); catalogued as COSV52132953; called by muse, varscan2
- SLITRK1 | c.262C>A p.H88N | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV65676152; called by muse, mutect2, varscan2
- SMARCA1 | c.1168-1G>C p.X390_splice | Splice Site (SNP) | VAF 29/179 reads (16%) | catalogued as COSV64412335; called by muse, mutect2, varscan2
- SNRNP200 | c.3280G>A p.A1094T | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60490564; called by muse, mutect2, varscan2
- SOX6 | c.1289G>C p.R430P (on ENST00000528429 / NM_001145819.2; = p.R389P on NM_017508.3) | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV57048481, COSV57049768; called by muse, mutect2, varscan2
- SP6 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60617949; called by muse, mutect2, varscan2
- SPAST | c.137A>C p.H46P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV59514976; called by muse, varscan2
- SPTB | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 46/168 reads (27%) | catalogued as COSV67629729, COSV67632569; called by muse, mutect2, varscan2
- ST18 | c.2752G>T p.G918W | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52492804, COSV52496870; called by muse, mutect2, varscan2
- STAB2 | c.4036C>A p.Q1346K | Missense Mutation (SNP) | VAF 79/129 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as COSV66340552; called by muse, mutect2, varscan2
- STARD13 | c.212G>C p.G71A | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55232006; called by muse, mutect2, varscan2
- SYT4 | c.353T>A p.L118Q | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.305); catalogued as COSV54901137; called by muse, mutect2, varscan2
- TAAR5 | c.970G>C p.V324L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV57799208; called by muse, mutect2, varscan2
- TBC1D16 | c.1609G>T p.V537L | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV60478519; called by muse, mutect2, varscan2
- TBC1D32 | c.3694G>C p.E1232Q | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV51545243, COSV99249094; called by muse, mutect2, varscan2
- TBL1XR1 | c.98A>G p.H33R | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.677); catalogued as rs919621560, COSV61790874; called by muse, mutect2, varscan2
- TBX3 | c.1766C>T p.S589F (on ENST00000257566 / NM_016569.4; = p.S569F on NM_005996.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57472466; called by muse, mutect2, varscan2
- TENM2 | c.1373C>G p.T458R (on ENST00000518659 / NM_001122679.2; = p.T226R on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV69132543; called by muse, mutect2, varscan2
- TEX14 | c.4200G>C p.E1400D (on ENST00000240361 / NM_001201457.2; = p.E1354D on NM_031272.5) | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53618861; called by muse, mutect2
- THSD7A | c.2440T>A p.C814S | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70266169; called by muse, mutect2, varscan2
- TMEM132D | c.1285G>T p.V429L | Missense Mutation (SNP) | VAF 146/252 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs750542701, COSV70608353; called by muse, mutect2, varscan2
- TNR | c.2173G>T p.G725W | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54890550; called by muse, mutect2
- TRIM42 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53883785; called by muse, mutect2, varscan2
- TRIML2 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV58715593, COSV58716798; called by muse, mutect2, varscan2
- TRIP12 | c.4237G>A p.G1413S | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV52265318; called by muse, mutect2, varscan2
- TRMT13 | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV54928341; called by muse, mutect2, varscan2
- TSSK1B | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV101181058; called by muse, mutect2, varscan2
- UBQLN1 | c.1495G>T p.G499* | Nonsense Mutation (SNP) | VAF 94/176 reads (53%) | catalogued as COSV57408248; called by muse, mutect2, varscan2
- UGT3A1 | c.1498A>G p.M500V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs757198568, COSV99954669; called by mutect2, varscan2
- USP29 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV54143538; called by muse, mutect2, varscan2
- VCAN | c.4952C>A p.T1651K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754005685, COSV54107264; called by muse, mutect2, varscan2
- VPS13A | c.1888A>G p.K630E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV62431423; called by muse, mutect2
- WDR49 | c.1350G>T p.E450D (on ENST00000308378 / NM_001366158.1; = p.E791D on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV57705933; called by muse, mutect2, varscan2
- XRCC6 | c.589+1G>T p.X197_splice | Splice Site (SNP) | VAF 20/97 reads (21%) | catalogued as COSV63753015; called by muse, mutect2, varscan2
- ZAN | c.1762A>G p.K588E | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.46); catalogued as COSV61810225; called by muse, mutect2, varscan2
- ZEB1 | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1429021087, COSV58046147; called by muse, mutect2, varscan2
- ZNF300 | c.1049A>T p.E350V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51032203, COSV51036491; called by muse, mutect2, varscan2
- ZNF516 | c.2634G>T p.W878C | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV71587137; called by muse, mutect2, varscan2
- ZNF518A | c.4183C>T p.P1395S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1365480100, COSV60151674; called by muse, mutect2, varscan2
- ZNF761 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV61888606; called by muse, mutect2, varscan2
- ZNF808 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV63120218; called by muse, mutect2, varscan2
- ZNF827 | c.878A>T p.E293V | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65228059; called by muse, mutect2, varscan2
- ZW10 | c.1422G>T p.L474F | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.174); catalogued as COSV52317089; called by muse, mutect2, varscan2
- GAGE1 | c.206-1G>A p.X69_splice | Splice Site (SNP) | VAF 37/400 reads (9%) | called by muse, varscan2
- ILDR1 | c.1490del p.R497Pfs*83 (on ENST00000344209 / NM_001199799.2; = p.R453Pfs*83 on NM_175924.4) | Frame Shift Del (DEL) | VAF 17/37 reads (46%) | called by mutect2, pindel, varscan2
- KIR2DS4 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.11005del p.R3669Efs*87 | Frame Shift Del (DEL) | VAF 79/271 reads (29%) | called by mutect2, pindel, varscan2
- MGAT5 | c.473del p.G158Efs*6 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- NRBP1 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2
- PCDHA12 | c.2367+3A>C | Splice Region (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- PIK3R4 | c.514_532del p.P172Tfs*35 | Frame Shift Del (DEL) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- PRR5L | c.842dup p.E282Gfs*38 | Frame Shift Ins (INS) | VAF 40/77 reads (52%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 178/546 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- SPOCK3 | c.988dup p.V330Gfs*13 | Frame Shift Ins (INS) | VAF 23/114 reads (20%) | called by mutect2, pindel, varscan2
- TANC2 | c.1919del p.G640Afs*18 | Frame Shift Del (DEL) | VAF 29/238 reads (12%) | called by mutect2, pindel, varscan2
- TRAV7 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRBV4-2 | c.32T>A p.L11H | Missense Mutation (SNP) | VAF 148/479 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ACAT2 | c.990A>G p.A330= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV58459224; called by muse, mutect2, varscan2
- ADAMTS6 | c.3339C>A p.T1113= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs369188012, COSV100068372; called by muse, mutect2, varscan2
- ADCY2 | c.936C>A p.V312= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs1309493439, COSV57877179; called by muse, mutect2, varscan2
- AGO2 | c.2565C>T p.T855= | Silent (SNP) | VAF 38/200 reads (19%) | catalogued as COSV55048354; called by muse, mutect2, varscan2
- ANKS4B | c.1236G>T p.L412= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV61139342; called by muse, mutect2, varscan2
- ANXA11 | c.705G>A p.R235= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1486978367, COSV55417171; called by muse, mutect2, varscan2
- ASXL3 | c.4959A>C p.S1653= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99324705; called by muse, varscan2
- ATP8B2 | c.3225G>T p.G1075= (on ENST00000672630; = p.G1042= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 42/252 reads (17%) | catalogued as rs774600862, COSV59246494; called by muse, varscan2
- CASP7 | c.310C>T p.L104= | Silent (SNP) | VAF 59/223 reads (26%) | catalogued as COSV61882068; called by muse, mutect2, varscan2
- CCDC85A | c.942G>T p.P314= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV68151869; called by muse, mutect2, varscan2
- CCNB3 | c.4152G>A p.L1384= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV52074739; called by muse, mutect2, varscan2
- CELSR2 | c.6222C>T p.V2074= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV54773592; called by muse, mutect2, varscan2
- CES5A | c.1017C>T p.I339= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs776403680, COSV51867242; called by muse, mutect2, varscan2
- COBL | c.642C>T p.N214= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs755973608, COSV54348207; called by muse, mutect2, varscan2
- CPEB1 | c.672A>T p.S224= (on ENST00000617958; = p.S164= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as COSV55619459, COSV99917739; called by muse, mutect2, varscan2
- CTNNA2 | c.2217T>A p.S739= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV58156296; called by muse, mutect2, varscan2
- CYLC2 | c.465A>T p.L155= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV66337575; called by muse, mutect2, varscan2
- CYYR1 | c.426T>C p.R142= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV54833206; called by muse, mutect2, varscan2
- DAGLA | c.2703C>G p.R901= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV57196930; called by muse, mutect2, varscan2
- DBN1 | c.1356C>T p.T452= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as rs886653292, COSV52790104; called by muse, mutect2, varscan2
- DCAF12L2 | c.888C>A p.S296= | Silent (SNP) | VAF 46/282 reads (16%) | catalogued as COSV63582133, COSV63583009; called by muse, mutect2, varscan2
- DDO | c.939G>T p.V313= (on ENST00000368924 / NM_001368172.1; = p.V254= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV64469685; called by muse, mutect2, varscan2
- DNAH9 | c.13071T>A p.T4357= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV52354087; called by muse, mutect2, varscan2
- DSC1 | c.441G>T p.S147= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV57146571; called by muse, mutect2, varscan2
- EPHB1 | c.1959G>T p.L653= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV67663039; called by muse, mutect2, varscan2
- ERICH1 | c.1131G>T p.A377= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV50638596; called by muse, mutect2, varscan2
- ESPNL | c.1752C>A p.P584= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV58035306; called by muse, varscan2
- EYA1 | c.1023T>G p.T341= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV58164830; called by muse, mutect2, varscan2
- FAT2 | c.8778G>T p.A2926= | Silent (SNP) | VAF 32/263 reads (12%) | catalogued as rs374640362, COSV55821401; called by muse, mutect2, varscan2
- FGF12 | c.342T>G p.R114= (on ENST00000454309 / NM_021032.5; = p.R52= on NM_004113.6) | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, varscan2
- FGF13 | c.147C>A p.V49= | Silent (SNP) | VAF 33/213 reads (15%) | catalogued as COSV59546565; called by muse, mutect2, varscan2
- FRMPD4 | c.2904G>T p.S968= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as rs768684415, COSV66216485, COSV66223530; called by muse, mutect2, varscan2
- GPC2 | c.771C>T p.L257= | Silent (SNP) | VAF 55/331 reads (17%) | catalogued as COSV52783724, COSV52785327; called by muse, mutect2
- GPC6 | c.102C>T p.R34= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV65514783; called by muse, mutect2, varscan2
- GPR150 | c.195C>T p.C65= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs777499038, COSV101187403; called by muse, varscan2
- HKDC1 | c.954C>T p.L318= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV63577549; called by muse, mutect2, varscan2
- IGSF5 | c.672C>A p.A224= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV66030520; called by muse, mutect2, varscan2
- KCNJ12 | c.951G>A p.L317= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1555562825, COSV59167947; called by mutect2, varscan2
- KIDINS220 | c.2466G>C p.V822= | Silent (SNP) | VAF 35/256 reads (14%) | catalogued as COSV56752003, COSV56754448; called by muse, mutect2, varscan2
- KIF4B | c.2112G>T p.T704= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as COSV70529918; called by muse, mutect2, varscan2
- KIR2DS4 | c.87T>G p.P29= | Silent (SNP) | VAF 78/231 reads (34%) | called by muse, mutect2, varscan2
- KRT2 | c.1366T>C p.L456= | Silent (SNP) | VAF 25/188 reads (13%) | catalogued as COSV59010834; called by muse, mutect2, varscan2
- LRP1B | c.13260C>T p.N4420= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV67231325, COSV67244851; called by muse, mutect2, varscan2
- LVRN | c.2745T>A p.A915= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV63496392, COSV63497452; called by muse, mutect2, varscan2
- MACC1 | c.1131C>T p.P377= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV60543677; called by muse, mutect2, varscan2
- MC2R | c.456G>A p.T152= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs760107296, COSV100562837; called by muse, mutect2, varscan2
- MGRN1 | c.1029C>G p.P343= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- MGRN1 | c.1149A>C p.P383= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV99274094; called by muse, mutect2, varscan2
- MROH8 | c.909G>A p.L303= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV54117812; called by muse, mutect2, varscan2
- MXRA5 | c.2415T>A p.I805= | Silent (SNP) | VAF 50/198 reads (25%) | catalogued as COSV54238312; called by muse, mutect2, varscan2
- MYT1L | c.733C>A p.R245= | Silent (SNP) | VAF 62/179 reads (35%) | catalogued as COSV67722156; called by muse, mutect2, varscan2
- NAALAD2 | c.555C>T p.N185= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV58961892; called by muse, mutect2, varscan2
- NBAS | c.2847G>T p.V949= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV55724852; called by muse, mutect2, varscan2
- NMUR2 | c.1125C>A p.T375= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV54917788, COSV54920076; called by muse, mutect2, varscan2
- NUP160 | c.3786A>G p.A1262= | Silent (SNP) | VAF 50/98 reads (51%) | catalogued as COSV65854651; called by muse, mutect2, varscan2
- OR10G2 | c.555C>T p.D185= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as COSV73390392; called by muse, mutect2, varscan2
- OR10T2 | c.618G>T p.L206= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV57781696; called by muse, mutect2, varscan2
- OR2W3 | c.747C>A p.S249= | Silent (SNP) | VAF 33/236 reads (14%) | catalogued as COSV64456481; called by muse, mutect2, varscan2
- PBXIP1 | c.1443G>A p.G481= | Silent (SNP) | VAF 96/668 reads (14%) | catalogued as rs1265633437, COSV63777307; called by muse, mutect2, varscan2
- PCDHA7 | c.621G>A p.E207= | Silent (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- PCDHB16 | c.429G>T p.P143= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV53363811; called by muse, mutect2, varscan2
- PCDHB16 | c.1356C>T p.T452= | Silent (SNP) | VAF 69/216 reads (32%) | catalogued as COSV53363827; called by muse, mutect2, varscan2
- PER3 | c.2968C>T p.L990= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV62706296; called by muse, varscan2
- PHACTR3 | c.858G>T p.R286= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV63029125; called by muse, mutect2, varscan2
- PLAAT3 | c.477A>G p.R159= | Silent (SNP) | VAF 63/163 reads (39%) | catalogued as rs763585398, COSV60311634; called by muse, mutect2, varscan2
- PLCD3 | c.1302C>T p.C434= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs369060547; called by muse, mutect2, varscan2
- PLEKHA6 | c.1936C>A p.R646= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV55334926, COSV55336251; called by muse, mutect2, varscan2
- PLOD1 | c.210G>T p.T70= | Silent (SNP) | VAF 49/201 reads (24%) | catalogued as COSV99538212; called by muse, mutect2, varscan2
- PNMA3 | c.1212C>A p.G404= | Silent (SNP) | VAF 28/182 reads (15%) | catalogued as COSV100937587; called by muse, mutect2, varscan2
- PRIMA1 | c.252C>A p.P84= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV60264034; called by muse, mutect2, varscan2
- PSD2 | c.1509G>T p.L503= | Silent (SNP) | VAF 103/259 reads (40%) | catalogued as COSV51201791; called by muse, mutect2, varscan2
- PTPRR | c.1689C>A p.P563= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV51735101; called by muse, mutect2, varscan2
- RABGEF1 | c.1320C>T p.I440= (on ENST00000439720 / NM_001287061.2; = p.I427= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as COSV53162847; called by muse, mutect2
- RANBP17 | c.51T>C p.H17= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV66651560; called by muse, mutect2, varscan2
- RBM12 | c.2655A>T p.S885= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as COSV58292163; called by muse, mutect2, varscan2
- SACS | c.10284A>T p.T3428= | Silent (SNP) | VAF 11/168 reads (7%) | catalogued as COSV66541229; called by muse, mutect2
- SLC15A2 | c.606A>G p.T202= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV55198330; called by muse, mutect2, varscan2
- SORL1 | c.2682C>T p.D894= | Silent (SNP) | VAF 28/318 reads (9%) | catalogued as COSV52755931; called by muse, mutect2
- SPG11 | c.5352C>T p.A1784= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV55996180; called by muse, mutect2, varscan2
- STX8 | c.609G>T p.R203= | Silent (SNP) | VAF 70/280 reads (25%) | catalogued as COSV60491789; called by muse, mutect2, varscan2
- TARBP1 | c.1386A>G p.P462= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV50182005; called by muse, mutect2, varscan2
- TENM4 | c.4668G>A p.G1556= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as rs768666205, COSV53636059; called by muse, mutect2, varscan2
- TIGIT | c.660C>T p.A220= | Silent (SNP) | VAF 40/277 reads (14%) | catalogued as rs751792806, COSV67329031; called by muse, mutect2, varscan2
- TIMMDC1 | c.153G>A p.P51= | Silent (SNP) | VAF 88/294 reads (30%) | catalogued as COSV51786914; called by muse, mutect2, varscan2
- TLCD3B | c.75G>T p.R25= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV54227350; called by muse, mutect2
- TMEM204 | c.537C>A p.A179= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99559887; called by muse, mutect2, varscan2
- TRIM41 | c.928C>T p.L310= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100163186; called by muse, mutect2, varscan2
- TRIML1 | c.771C>T p.L257= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV60194686; called by muse, mutect2, varscan2
- TXLNG | c.1425T>A p.P475= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100417892; called by muse, mutect2, varscan2
- TXNDC16 | c.1641A>T p.A547= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV55985092; called by muse, mutect2, varscan2
- VARS1 | c.2934C>T p.G978= | Silent (SNP) | VAF 64/109 reads (59%) | catalogued as COSV63304726; called by muse, mutect2, varscan2
- ZBTB7B | c.1347C>G p.L449= (on ENST00000292176; = p.L483= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV52693033; called by muse, mutect2
- ZFYVE26 | c.7368C>T p.P2456= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV61329540; called by muse, mutect2, varscan2
- ZNF354C | c.871C>T p.L291= | Silent (SNP) | VAF 40/184 reads (22%) | catalogued as COSV59608574; called by muse, mutect2, varscan2
- ZNF395 | c.1500G>C p.T500= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100733982, COSV60428951; called by muse, mutect2, varscan2
- ZNF524 | c.636G>T p.T212= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs925661964, COSV55607467, COSV55608040; called by muse, mutect2, varscan2
- ZNF644 | c.3885G>T p.R1295= (on ENST00000337393 / NM_201269.3; = p.R73= on NM_016620.3) | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV61348203; called by muse, mutect2, varscan2
- ZSCAN1 | c.156G>T p.P52= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV56605217; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504169 G>C | 5'Flank (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500250 G>C | 5'Flank (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- DCHS2 | n.7756G>T | RNA (SNP) | VAF 32/143 reads (22%) | catalogued as COSV61771389; called by muse, mutect2, varscan2
- KCNH7 | c.2154+38del | Intron (DEL) | VAF 59/174 reads (34%) | catalogued as COSV59785647; called by mutect2, pindel, varscan2
- MORF4 | n.789C>A | RNA (SNP) | VAF 63/200 reads (32%) | called by muse, varscan2
- PCDH11X | c.3033+3650C>A | Intron (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100011334; called by muse, mutect2, varscan2
